TCGA case TCGA-A7-A26I — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b2ecbc0f-2c30-4200-8d5e-7b95424bcadb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 65.6 years (23,948 days); Year of diagnosis: 2011; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 164 days; Number of cycles: 6; Treatment dose: 6,780 mg; Prescribed dose: 1130; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 164 days; Number of cycles: 6; Treatment dose: 840 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 213 days; Days to treatment end: 258 days; Treatment dose: 6,100 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Indeterminate; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Right; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 369 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 661 days (1.8 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 122.

Molecular and laboratory tests
- ERBB2 (FISH): 1.1; Cell count: 229; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 2.2; Cell count: 229.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.
- Test (FISH): Copy Number Reported; Copy number: 2; Cell count: 229.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A7-A26I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-A7-A26I-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A26I-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide TCGA-A7-A26I-01B-05-BS5: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A26I-01B-06-BS6: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A26I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A7-A26I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Lymph nodes examined: Yes; Her2 cent17 ratio: 1.1; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Lumpectomy; Surgery for positive margins other: Re-Excision of Superior Margin; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Her2 IHC score: 2+; Margin status: Close; Method initial path diagnosis: Fine needle aspiration biopsy; Her2 fish method: Path Vysion HER-2 DNA probe kit; Prospective collection: Yes; Retrospective collection: No; Cent17 copy number: 2.0; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Taxotere.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Leg; Other malignancy histological type: Basal-Cell Carcinoma, Superficial.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -309.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 661 days; disease-specific survival: no event (censored), 661 days; disease-free interval: no event (censored), 661 days; progression-free interval: no event (censored), 661 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A7-A26I-01A-11D-A166-01): tumor purity 0.55, ploidy 3.09, whole-genome doublings 1.
